Gene-level copy-number profile of tumor specimen TCGA-24-1852-02A from TCGA case TCGA-24-1852, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.8 years (20,390 days).
Specimen TCGA-24-1852-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1272a812-779f-45fb-a7df-9b1a29a4550e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1852-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 370 have no estimate.
https://portal.gdc.cancer.gov/files/63de66ed-3a04-478d-bf15-37022fd37e3e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 404; copy number 1: 593; copy number 2: 6,264; copy number 3: 15,696; copy number 4: 18,107; copy number 5: 8,764; copy number 6: 6,081; copy number 7: 2,024; copy number 8: 797; copy number 9: 267; copy number 10: 476; copy number 11: 251; copy number 12: 119; copy number 13: 55; copy number 14: 88; copy number 18: 119; copy number 20: 103; copy number 22: 19; copy number 23: 26.

Homozygous deletions (total copy number 0; autosomes only): 122 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–4): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr17:20,321,164–22,706,703, 113 genes (broad region; genes not listed).
- chr17:75,588,058–75,667,189, 4 genes (within-gene range 0–10): MYO15B, RECQL5, SMIM5, SMIM6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,425 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,681,249–248,919,946, 14 genes, copy number 22: CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr2:88,811,186–88,861,563, 1 gene, copy number 12 (within-gene range 4–12): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 12: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr8:38,844,866–38,846,439, 1 gene, copy number 11: AC067817.2.
- chr8:52,110,839–64,369,176, 180 genes, copy number 12–23 (within-gene range 3–23) (broad region; genes not listed).
- chr8:142,834,247–142,916,506, 1 gene, copy number 11 (within-gene range 6–11): GML.
- chr8:142,872,356–144,118,328, 76 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr11:69,641,156–69,675,416, 2 genes, copy number 14 (within-gene range 5–14): CCND1, LTO1.
- chr11:72,836,745–73,142,318, 1 gene, copy number 14 (within-gene range 5–14): FCHSD2.
- chr11:73,157,946–79,441,030, 182 genes, copy number 12–18 (within-gene range 8–18) (broad region; genes not listed).
- chr12:66,767–8,396,803, 288 genes, copy number 9–12 (broad region; genes not listed).
- chr12:8,858,143–11,176,016, 112 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr12:26,905,181–28,581,511, 41 genes, copy number 11–12 (within-gene range 8–12): INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P.
- chr12:41,658,676–42,238,349, 10 genes, copy number 9: RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2.
- chr17:33,565,764–33,816,761, 6 genes, copy number 10: AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4.
- chr17:34,479,272–34,859,046, 6 genes, copy number 10: AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1.
- chr17:73,334,384–75,575,209, 85 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr17:75,667,251–75,708,062, 3 genes, copy number 9: SAP30BP, AC087749.2, AC087749.1.
- chr19:12,646,511–16,628,204, 223 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr19:21,932,958–22,130,489, 9 genes, copy number 11: ZNF208, MTDHP2, AC003973.2, BNIP3P28, AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2.
- chr19:29,083,094–29,233,385, 6 genes, copy number 13: AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P.
- chr19:29,606,283–30,085,893, 16 genes, copy number 12: POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr19:30,907,199–31,147,981, 3 genes, copy number 12: LINC01834, AC020897.1, AC020912.1.
- chr19:34,734,155–34,832,869, 6 genes, copy number 10: ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5.
- chr19:35,268,962–35,563,658, 23 genes, copy number 11 (within-gene range 3–11): USF2, HAMP, MAG, CD22, U62631.1, MIR5196, FFAR1, FFAR3, GPR42, EEF1A1P7, LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2, KRTDAP, DMKN, SBSN, GAPDHS, TMEM147-AS1, TMEM147, ATP4A.
- chr19:35,758,143–36,014,239, 21 genes, copy number 9 (within-gene range 3–9): PROSER3, AC002398.1, ARHGAP33, LINC01529, PRODH2, NPHS1, KIRREL2, APLP1, RN7SL402P, NFKBID, AD000864.1, HCST, TYROBP, LRFN3, AF038458.3, AF038458.1, AF038458.2, SDHAF1, SYNE4, AC002116.1, ALKBH6.
- chr19:36,014,660–36,033,343, 1 gene, copy number 9 (within-gene range 5–9): CLIP3.
- chr19:38,867,830–39,400,641, 32 genes, copy number 11: RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29.
- chr19:57,230,802–57,889,074, 52 genes, copy number 9–13 (within-gene range 2–13): AURKC, ZNF805, AC005261.3, ZNF460-AS1, ZNF460, AC005261.5, AC005261.1, AC005261.4, ZNF543, AC005261.2, ZNF304, ZNF547, TRAPPC2B, AC003002.1, ZNF548, AC003002.3, AC003002.2, ZNF17, ZNF749, AC004076.1, AC004076.2, VN1R1, VN1R107P, ZNF772, AC003005.2, ZNF419, AC003005.1, ZNF773, ZNF549, ZNF550, ZNF416, ZIK1, ZNF530, ZNF134, AC003682.1, ZNF211, TPRG1LP1, ZSCAN4, ZNF551, AC003006.1, ZNF154, ZNF671, ZNF776, ZNF586, ZNF552, AC010522.1, ZNF587B, FKBP1AP1, ZNF814, ZNF587, AC010326.3, AC010326.4.

Autosomal genes at a single copy (total copy number 1): 355. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
